Somatic mutation profile of tumor specimen C3L-00987-01 (aliquot CPT0127050006) from CPTAC case C3L-00987, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 61.4 years (22,430 days).
Specimen C3L-00987-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d435b10-44bc-4374-a56e-c0896c9cc94a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00987-31 (Blood Derived Normal), aliquot CPT0128500002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/699b2411-96eb-42f8-8d74-61ae14dce17e

The open-access MAF lists 96 somatic variants for this specimen: 67 protein-altering or splice-affecting, 20 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 20, Intron 6, Nonsense Mutation 5, Frame Shift Del 3, Frame Shift Ins 3, In Frame Del 3, Splice Site 2, In Frame Ins 1, RNA 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.4628G>A p.G1543E | Missense Mutation (SNP) | VAF 82/473 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.279); catalogued as rs753807315, COSV61362359; called by muse, mutect2, varscan2
- ADCY10 | c.737A>G p.K246R | Missense Mutation (SNP) | VAF 59/222 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs1273823831; called by muse, mutect2, varscan2
- ASL | c.584A>G p.N195S | Missense Mutation (SNP) | VAF 96/316 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.158); catalogued as rs1409298819, CD073570; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCKDK | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 67/227 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs774302251; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRINP2 | c.878A>T p.N293I | Missense Mutation (SNP) | VAF 54/424 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as rs1300008782; called by muse, mutect2, varscan2
- COG5 | c.1562A>C p.K521T | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1243848853; called by muse, mutect2, varscan2
- COL11A1 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 81/210 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as rs752749747, COSV100617349, COSV62180341; called by muse, mutect2, varscan2
- CPS1 | c.719C>A p.A240D | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV51805306; called by muse, mutect2, varscan2
- CRACDL | c.1487del p.S496Tfs*3 | Frame Shift Del (DEL) | VAF 23/69 reads (33%) | catalogued as COSV67409454; called by mutect2, pindel, varscan2
- DNAAF5 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 28/386 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375829727; called by muse, mutect2
- DOHH | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 16/375 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436175406, COSV51744268; called by muse, mutect2
- ITIH2 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs144713735; called by muse, mutect2, varscan2
- ITSN2 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs772038579, COSV61946739; called by muse, mutect2, varscan2
- KMT2D | c.4828A>T p.K1610* | Nonsense Mutation (SNP) | VAF 117/292 reads (40%) | catalogued as COSV56489645; called by muse, mutect2, varscan2
- LMF1 | c.841C>T p.L281F | Missense Mutation (SNP) | VAF 68/292 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as rs1326465253; called by muse, varscan2
- MGAT3 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 115/389 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs1159901010; called by muse, mutect2, varscan2
- NBPF11 | c.1939C>G p.L647V | Missense Mutation (SNP) | VAF 139/654 reads (21%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.874); catalogued as rs200407900, COSV65042688; called by muse, mutect2, varscan2
- NLE1 | c.824A>G p.H275R | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1171390576; called by muse, varscan2
- NLRP3 | c.299C>A p.S100* | Nonsense Mutation (SNP) | VAF 103/468 reads (22%) | catalogued as COSV60220208; called by muse, mutect2, varscan2
- PKHD1L1 | c.3847C>T p.Q1283* | Nonsense Mutation (SNP) | VAF 24/127 reads (19%) | catalogued as COSV65747651; called by muse, mutect2, varscan2
- PROSER3 | c.449A>G p.N150S | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1568409974; called by muse, mutect2, varscan2
- SVEP1 | c.4784C>T p.S1595F | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65691161; called by muse, mutect2, varscan2
- TENM3 | c.403T>A p.W135R | Missense Mutation (SNP) | VAF 72/178 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as rs767787511; called by muse, mutect2, varscan2
- TRIM50 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 159/557 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1261346505, COSV100297154; called by muse, mutect2, varscan2
- AKAP12 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.838); called by muse, mutect2
- BRD3 | c.1070A>G p.D357G | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDK13 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CDR2 | c.1302_1316del p.K435_E439del | In Frame Del (DEL) | VAF 34/129 reads (26%) | called by mutect2, pindel, varscan2
- CPS1 | c.3667G>A p.V1223M | Missense Mutation (SNP) | VAF 57/251 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CR1 | c.5796T>A p.D1932E | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CST3 | c.291_293del p.T98del | In Frame Del (DEL) | VAF 88/249 reads (35%) | called by mutect2, pindel, varscan2
- CSTF3 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2
- CYFIP1 | c.2276G>A p.G759D | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DMXL2 | c.5516G>A p.S1839N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); called by muse, mutect2
- FLG | c.3982C>G p.Q1328E | Missense Mutation (SNP) | VAF 202/725 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRM8 | c.2224T>C p.C742R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GYPB | c.223A>T p.I75F | Missense Mutation (SNP) | VAF 70/132 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- HECTD4 | c.7283_7290dup p.G2431Mfs*6 | Frame Shift Ins (INS) | VAF 25/102 reads (25%) | called by mutect2, varscan2
- HSPA8 | c.979G>C p.D327H | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- IFIT2 | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- KLF4 | c.324_325insATA p.I108dup | In Frame Ins (INS) | VAF 231/489 reads (47%) | called by mutect2, pindel, varscan2
- KMT2E | c.2370dup p.I791Yfs*2 | Frame Shift Ins (INS) | VAF 28/118 reads (24%) | called by mutect2, pindel, varscan2
- KRT72 | c.366_377del p.A123_R126del | In Frame Del (DEL) | VAF 36/190 reads (19%) | called by mutect2*, pindel, varscan2
- MAK16 | c.705+1G>A p.X235_splice | Splice Site (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- MFSD4A | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRTFA | c.2412G>A p.M804I | Missense Mutation (SNP) | VAF 80/290 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- NFE2L3 | c.1427G>A p.C476Y | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- NTHL1 | c.331G>A p.D111N (on ENST00000219066; = p.D103N on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/275 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- OR10J5 | c.347C>A p.T116N | Missense Mutation (SNP) | VAF 19/244 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); called by muse, mutect2
- OR5L2 | c.310T>A p.F104I | Missense Mutation (SNP) | VAF 66/313 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PCNT | c.5116-1G>A p.X1706_splice | Splice Site (SNP) | VAF 50/152 reads (33%) | called by muse, mutect2, varscan2
- PIEZO1 | c.4957C>A p.R1653S | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PIK3C2B | c.2205G>A p.W735* | Nonsense Mutation (SNP) | VAF 9/147 reads (6%) | called by muse, mutect2
- PLCD3 | c.1580_1582delinsT p.E527Vfs*120 | Frame Shift Del (DEL) | VAF 9/77 reads (12%) | called by pindel, varscan2*
- PLXNB2 | c.3782del p.E1261Gfs*36 | Frame Shift Del (DEL) | VAF 91/353 reads (26%) | called by mutect2, pindel, varscan2
- PRMT3 | c.687A>G p.I229M | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PUS7L | c.299A>G p.N100S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAD9B | c.222T>A p.S74R | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2
- SGCE | c.655T>A p.F219I (on ENST00000647096; = p.F183I on NM_003919.3) | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); called by muse, mutect2
- SGO2 | c.100T>A p.S34T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC12A1 | c.2456T>G p.F819C | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2
- TANGO6 | c.3166G>T p.E1056* | Nonsense Mutation (SNP) | VAF 57/278 reads (21%) | called by muse, mutect2, varscan2
- TLR3 | c.221A>G p.Y74C | Missense Mutation (SNP) | VAF 81/162 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TM9SF2 | c.1315T>C p.F439L | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF440 | c.478A>G p.R160G | Missense Mutation (SNP) | VAF 78/243 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- ZNF518B | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF845 | c.1781_1785dup p.N596Lfs*114 | Frame Shift Ins (INS) | VAF 30/141 reads (21%) | called by mutect2, varscan2
- APC | c.8145C>T p.T2715= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as rs1554088935, COSV57320884; ClinVar: likely benign; called by muse, mutect2, varscan2
- APC2 | c.6304C>T p.L2102= | Silent (SNP) | VAF 71/165 reads (43%) | called by muse, mutect2, varscan2
- ATP8B4 | c.3081G>A p.G1027= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as rs1381423073, COSV52712253; called by muse, mutect2
- CEACAM4 | c.144A>C p.G48= | Silent (SNP) | VAF 58/170 reads (34%) | called by muse, mutect2, varscan2
- DBF4 | c.474A>T p.I158= | Silent (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- FSCN2 | c.723C>A p.G241= | Silent (SNP) | VAF 25/102 reads (25%) | called by muse, mutect2, varscan2
- FSCN2 | c.724C>A p.R242= | Silent (SNP) | VAF 24/99 reads (24%) | called by muse, mutect2, varscan2
- HTR2B | c.405C>T p.D135= | Silent (SNP) | VAF 132/431 reads (31%) | catalogued as rs757281938; called by muse, mutect2, varscan2
- LONP2 | c.2479C>T p.L827= | Silent (SNP) | VAF 87/375 reads (23%) | called by muse, mutect2, varscan2
- NCOA6 | c.4609C>T p.L1537= | Silent (SNP) | VAF 57/317 reads (18%) | called by muse, mutect2, varscan2
- PAK4 | c.45C>T p.S15= | Silent (SNP) | VAF 89/365 reads (24%) | called by muse, mutect2, varscan2
- PANK1 | c.540G>A p.P180= | Silent (SNP) | VAF 54/216 reads (25%) | called by muse, mutect2, varscan2
- PKN1 | c.1704G>A p.R568= | Silent (SNP) | VAF 18/358 reads (5%) | called by muse, mutect2
- PXDNL | c.3867G>A p.K1289= | Silent (SNP) | VAF 79/269 reads (29%) | called by muse, mutect2, varscan2
- RBBP6 | c.1146G>T p.P382= | Silent (SNP) | VAF 68/288 reads (24%) | catalogued as COSV60504269; called by muse, varscan2
- SPAG4 | c.444C>A p.S148= | Silent (SNP) | VAF 112/274 reads (41%) | catalogued as rs777825605; called by muse, mutect2, varscan2
- TRAF4 | c.1008C>T p.A336= | Silent (SNP) | VAF 114/400 reads (29%) | called by muse, mutect2, varscan2
- USP13 | c.726C>T p.N242= | Silent (SNP) | VAF 60/313 reads (19%) | catalogued as rs552007222; called by muse, mutect2, varscan2
- VSIG10L | c.973C>T p.L325= | Silent (SNP) | VAF 82/295 reads (28%) | called by muse, mutect2, varscan2
- ZNF276 | c.945C>T p.D315= (on ENST00000443381 / NM_001113525.2; = p.D240= on NM_152287.4) | Silent (SNP) | VAF 15/268 reads (6%) | catalogued as rs771288582, COSV57067796, COSV99235273; called by muse, mutect2
- AC092865.4 | chr12:8390691 ins AGGG | 5'Flank (INS) | VAF 35/74 reads (47%) | called by mutect2, pindel, varscan2
- ATXN7L1 | c.355+27163A>G | Intron (SNP) | VAF 54/236 reads (23%) | called by muse, mutect2, varscan2
- CYFIP1 | c.1675-99G>A | Intron (SNP) | VAF 99/321 reads (31%) | catalogued as rs376121137; called by muse, mutect2, varscan2
- MAN1B1 | c.219+241_219+259del | Intron (DEL) | VAF 38/225 reads (17%) | called by mutect2, pindel, varscan2
- MAX | c.295+315A>G | Intron (SNP) | VAF 28/84 reads (33%) | catalogued as rs1350604508; called by muse, mutect2, varscan2
- OR7E5P | n.229C>T | RNA (SNP) | VAF 36/537 reads (7%) | called by muse, mutect2
- PNPO | c.417+35C>A | Intron (SNP) | VAF 91/313 reads (29%) | called by muse, mutect2, varscan2
- TMEM106A | c.615-4_615-3del | Intron (DEL) | VAF 27/159 reads (17%) | catalogued as rs748981220; called by pindel, varscan2
- XIAP | c.*4776A>G | 3'UTR (SNP) | VAF 60/92 reads (65%) | called by muse, mutect2, varscan2
